Somatic mutation profile of tumor specimen MP2PRT-PASVMH-TMP1-A (aliquot MP2PRT-PASVMH-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASVMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Blood; Age at diagnosis: 5.6 years (2,048 days).
Specimen MP2PRT-PASVMH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6619efc2-7441-41a9-923d-64c34e77416d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVMH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVMH-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f0739ad-5c2d-4d1b-95b5-17e61821b7f0

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Ins 2, Nonsense Mutation 2, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT4 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 392/935 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766622097, COSV57335713; called by muse, mutect2, varscan2
- CCSER1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 115/338 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1422192912; called by muse, mutect2, varscan2
- DCAF4L1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 115/784 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1226690767; called by muse, mutect2, varscan2
- GP2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 254/714 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs200111828, COSV56895251, COSV56896013; called by muse, mutect2, varscan2
- JPH1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 512/1269 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100646547, COSV60610627; called by muse, mutect2, varscan2
- KIF2B | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 224/571 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs761182386, COSV52128758; called by muse, mutect2, varscan2
- MAPT | c.638G>A p.R213Q (on ENST00000262410 / NM_001377265.1; = p.R138Q on NM_016835.4) | Missense Mutation (SNP) | VAF 438/1158 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.096); catalogued as rs756266318; called by muse, mutect2, varscan2
- NR3C1 | c.2194C>G p.L732V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.576); catalogued as COSV51541607; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 291/770 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA4 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 244/652 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs373176783; called by muse, mutect2, varscan2
- STS | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 340/900 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs759021618; called by muse, mutect2, varscan2
- THBS2 | c.2464G>T p.D822Y | Missense Mutation (SNP) | VAF 207/553 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64679839; called by muse, mutect2, varscan2
- TNFSF11 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 19/272 reads (7%) | catalogued as rs267603829, CM1313755, COSV53477301; called by muse, mutect2
- GBF1 | c.2464G>A p.D822N (on ENST00000369983 / NM_001377137.1; = p.D821N on NM_004193.3) | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHV3-13 | chr14:106129537 GTGTCTCTT>CCCCCTCG | Missense Mutation (DEL) | VAF 87/114 reads (76%) | called by pindel, varscan2*
- KDM6B | c.1621C>G p.H541D | Missense Mutation (SNP) | VAF 344/916 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- METRNL | c.392T>A p.V131E | Missense Mutation (SNP) | VAF 458/1228 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2
- NOL8 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SLC9A4 | c.1275C>G p.F425L | Missense Mutation (SNP) | VAF 126/322 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SLCO4C1 | c.285_286insGGGTC p.Q96Gfs*28 | Frame Shift Ins (INS) | VAF 185/559 reads (33%) | called by mutect2, pindel, varscan2
- TRAFD1 | c.601C>G p.Q201E | Missense Mutation (SNP) | VAF 37/484 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2
- UBA2 | c.1414A>T p.K472* | Nonsense Mutation (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- ZC3H12D | c.127_128insAGGG p.T43Kfs*54 | Frame Shift Ins (INS) | VAF 283/865 reads (33%) | called by mutect2, pindel, varscan2
- ARMC1 | c.129C>T p.G43= | Silent (SNP) | VAF 135/404 reads (33%) | catalogued as rs1238781211; called by muse, mutect2, varscan2
- BLOC1S3 | c.231G>T p.P77= | Silent (SNP) | VAF 568/1410 reads (40%) | called by muse, varscan2
- ERV3-1 | c.1251C>G p.L417= | Silent (SNP) | VAF 215/611 reads (35%) | called by muse, mutect2, varscan2
- FZD8 | c.882C>T p.A294= | Silent (SNP) | VAF 76/1030 reads (7%) | called by muse, mutect2
- LGI3 | c.1152C>T p.G384= | Silent (SNP) | VAF 331/862 reads (38%) | catalogued as rs201217019; called by muse, mutect2, varscan2
- OR5K2 | c.747A>G p.S249= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs912769490; called by muse, mutect2, varscan2
- GALNS | c.120+493dup | Intron (INS) | VAF 393/1112 reads (35%) | called by mutect2, pindel, varscan2
- RAB4A | chr1:229269601 C>G | 5'Flank (SNP) | VAF 58/148 reads (39%) | called by muse, mutect2, varscan2
